Gene-level copy-number profile of tumor specimen ALCH-B2LY-TTP1-A from ALCHEMIST case ALCH-B2LY, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 56.4 years (20,586 days).
Specimen ALCH-B2LY-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a3747321-db3b-4d06-8a55-8328093821d5.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2LY-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,716 have no estimate.
https://portal.gdc.cancer.gov/files/043c9631-4d4d-4381-9302-4ec71a20b24a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 555; copy number 1: 21,544; copy number 2: 29,466; copy number 3: 5,750; copy number 4: 1,194; copy number 5: 390; copy number 6: 1; copy number 10: 1; copy number 14: 6.

Homozygous deletions (total copy number 0; autosomes only): 41 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,326,201–2,326,693, 1 gene (within-gene range 0–2): AL589739.1.
- chr1:12,791,397–12,831,410, 3 genes (within-gene range 0–1): PRAMEF1, LINC01784, PRAMEF11.
- chr1:20,482,391–20,508,151, 2 genes: CAMK2N1, MUL1.
- chr1:39,522,280–39,559,671, 1 gene (within-gene range 0–1): PPIEL.
- chr2:232,378,724–232,387,457, 3 genes: ALPP, AC068134.1, ECEL1P2.
- chr4:69,306,469–69,307,173, 1 gene (within-gene range 0–1): AC114786.3.
- chr7:150,944,961–150,978,321, 1 gene: KCNH2.
- chr7:156,944,721–156,945,645, 1 gene: AC006357.1.
- chr8:20,229,779–20,551,405, 6 genes: RNU6-892P, LZTS1, LZTS1-AS1, RNA5SP257, AC023403.1, AC022559.1.
- chr8:22,106,874–22,275,162, 12 genes: NUDT18, HR, REEP4, LGI3, SFTPC, BMP1, AC105206.1, AC105206.3, PHYHIP, MIR320A, POLR3D, AC105206.2.
- chr13:95,336,106–95,336,201, 1 gene: RNY4P27.
- chr16:89,906,157–89,920,973, 2 genes (within-gene range 0–1): AC092143.3, MC1R.
- chr19:19,512,418–19,546,659, 5 genes: TSSK6, NDUFA13, AC011448.1, YJEFN3, CILP2.
- chr22:41,922,032–41,926,806, 2 genes: TNFRSF13C, MIR378I.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 398 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:133,573,686–146,105,204, 193 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr3:168,249,522–174,378,005, 99 genes, copy number 5 (broad region; genes not listed).
- chr3:178,960,121–183,684,519, 98 genes, copy number 5 (broad region; genes not listed).
- chr21:46,690,764–46,691,226, 1 gene, copy number 10: RPL23AP4.
- chr22:21,370,064–21,451,463, 7 genes, copy number 6–14: AP000552.1, Metazoa_SRP, RIMBP3B, RN7SKP63, AP000552.3, Metazoa_SRP, HIC2.

Autosomal genes at a single copy (total copy number 1): 19,202. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
